Surgical pathology report (de-identified scan), TCGA case TCGA-HT-A614, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-A614-01A (Primary Tumor).

Pathology report for

Addendum Discussion:

Only rare MIB-1 reactive cells are present. Even in the most proliferative focus, a labeling index of only 0.3% is calculated.

Addendum Diagnosis:

Oligoastrocytoma, grade II

- MIB-1 LI = 0.3%

Microscopic Description:

Sections demonstrate a mildly to moderately hypercellular diffusely infiltrating glial neoplasm. The moderately atypical tumor cells include both classic oligodendroglioma and astrocytoma phenotypes with the former predominant. No mitotic figures are identified. There is no microvascular proliferation or necrosis.

ICD-O-3
Oligoastrocytoma 9382/3
Site: Supratentorial
JW 4/16/13

Source: NCI Genomic Data Commons file 87c25566-61ee-4622-af05-136c46747749 (TCGA-HT-A614.9E38FBA2-A9D8-4428-B586-A0C7E711EA14.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).